Somatic mutation profile of tumor specimen MP2PRT-PATVRV-TMP1-A (aliquot MP2PRT-PATVRV-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PATVRV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,074 days).
Specimen MP2PRT-PATVRV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec1d0f80-09f8-45f5-b633-167aeedcd6a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVRV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVRV-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45a1b8aa-48a3-4251-ba31-202ffbc34267

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 3, Frame Shift Del 1, In Frame Del 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 64/212 reads (30%) | catalogued as COSV60620561, COSV60631707; called by muse, mutect2, varscan2
- APEX1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375526265; called by muse, mutect2, varscan2
- ASTL | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 152/387 reads (39%) | catalogued as COSV60904606; called by muse, mutect2, varscan2
- CDH4 | c.579C>A p.I193= | Splice Region (SNP) | VAF 128/285 reads (45%) | catalogued as COSV100848168; called by muse, mutect2, varscan2
- DLGAP2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 151/831 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1253496098; called by muse, mutect2, varscan2
- H1-2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.753); catalogued as rs781281855, COSV59190279, COSV59190466; called by muse, mutect2, varscan2
- KEL | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 104/777 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs61729036, CM962683; called by muse, mutect2, varscan2
- NANOS2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 87/572 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs751534299, COSV100379544, COSV58025835; called by muse, mutect2, varscan2
- PGPEP1L | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as rs759520361; called by muse, mutect2, varscan2
- PLEKHG7 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 79/470 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as rs1312282040; called by muse, mutect2, varscan2
- RIPPLY3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs759464387, COSV61567172; called by muse, mutect2, varscan2
- RNF157 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs1331146743; called by muse, mutect2, varscan2
- SEMA4C | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 107/485 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs757508021; called by muse, mutect2, varscan2
- SLC12A4 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs142605989; called by muse, mutect2, varscan2
- SRCAP | c.7725_7727del p.S2576del | In Frame Del (DEL) | VAF 72/564 reads (13%) | catalogued as rs797046007; called by pindel, varscan2
- THBS1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1347334087, COSV52950931; called by muse, varscan2
- TRIM45 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 64/393 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99868214; called by muse, mutect2, varscan2
- COL1A2 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 25/500 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- CPS1 | c.4255A>C p.S1419R | Missense Mutation (SNP) | VAF 122/306 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.308); called by muse, mutect2
- DVL2 | c.1045_1053dup p.L349_V351dup | In Frame Ins (INS) | VAF 24/158 reads (15%) | called by mutect2, varscan2
- MAD1L1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 358/725 reads (49%) | called by muse, mutect2, varscan2
- MPP7 | c.606A>G p.I202M | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR5AC2 | c.693del p.K231Nfs*27 | Frame Shift Del (DEL) | VAF 33/234 reads (14%) | called by mutect2, pindel, varscan2
- SEMA3C | c.216T>A p.D72E | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- UGT2B11 | c.1271A>G p.D424G | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- DPP10 | c.303A>G p.G101= | Silent (SNP) | VAF 35/206 reads (17%) | catalogued as rs202131701; called by muse, mutect2, varscan2
- EPHA4 | c.789C>T p.N263= | Silent (SNP) | VAF 48/342 reads (14%) | catalogued as rs779199200; called by muse, mutect2, varscan2
- FMN2 | c.2262G>T p.V754= | Silent (SNP) | VAF 85/501 reads (17%) | catalogued as COSV60454896; called by muse, mutect2, varscan2
- HRNR | c.8478A>T p.S2826= | Silent (SNP) | VAF 34/446 reads (8%) | called by muse, mutect2
- KCNJ12 | c.171C>T p.F57= | Silent (SNP) | VAF 110/1330 reads (8%) | catalogued as rs540498635, COSV59163720, COSV99045351; called by muse, mutect2
- LHX5 | c.1116G>T p.G372= | Silent (SNP) | VAF 53/353 reads (15%) | called by muse, mutect2, varscan2
- RPS6KA1 | c.1167C>T p.D389= | Silent (SNP) | VAF 136/365 reads (37%) | catalogued as rs371215242; called by muse, mutect2, varscan2
- SPATA3 | c.315C>T p.R105= | Silent (SNP) | VAF 65/363 reads (18%) | catalogued as rs1282786535, COSV69201616; called by muse, mutect2, varscan2
- WDR37 | c.717T>G p.A239= | Silent (SNP) | VAF 73/418 reads (17%) | called by muse, mutect2, varscan2
- WDR72 | c.2985G>A p.A995= | Silent (SNP) | VAF 38/259 reads (15%) | catalogued as rs745403939, COSV64745745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
